TCGA case TCGA-ZC-AAA7 — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: University of Mannheim. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd06627d-1e86-4212-b53b-082686abee7e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 63 years; Vital status: Dead; Days to death: 853 days (2.3 years).

Diagnoses (1)
1. Thymic carcinoma, NOS: ICD-O-3 morphology code: 8586/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 63.7 years (23,265 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIa; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 853 days (2.3 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 853 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 853 days (2.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 178 cm; BMI: 21.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZC-AAA7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 360 mg.
  Slide TCGA-ZC-AAA7-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZC-AAA7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZC-AAA7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: IIa.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type C.
- Primary pathology: History myasthenia gravis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 853 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 853 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 853 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZC-AAA7-01A-11D-A427-01): tumor purity 0.36, ploidy 4.24, whole-genome doublings 1.
